Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3534, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3534-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

Right hemicolectomy specimen with tumor-free resection margins, with two tubular colonic mucosal membrane adenomas with mild dysplasia (synonym: low-grade intra-epithelial neoplasia) and under inclusion of an ulcerated, moderately differentiated adenocarcinoma of the ascending colon with infiltration of the perimuscular fatty tissue and without regional lymph node metastases (G2, pT3 pN0 0/36 L1 V0 R0).

Source: NCI Genomic Data Commons file ab8a6f6b-f896-4dcd-8a9c-dba91e049b90 (TCGA-AA-3534.55D94E20-9F25-4E4E-A7C1-13A21D2620FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).